Somatic mutation profile of tumor specimen TCGA-C5-A8XH-01A (aliquot TCGA-C5-A8XH-01A-11D-A37N-09) from TCGA case TCGA-C5-A8XH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Age at diagnosis: 39.5 years (14,444 days).
Specimen TCGA-C5-A8XH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d34c228-e434-425b-baa6-9d537c8b0f3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A8XH-10A (Blood Derived Normal), aliquot TCGA-C5-A8XH-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fa639b1-4460-4993-9bb5-d515bf7f7952

The open-access MAF lists 286 somatic variants for this specimen: 214 protein-altering or splice-affecting, 62 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 62, Nonsense Mutation 16, Frame Shift Del 11, Splice Site 8, Intron 7, In Frame Del 5, Splice Region 3, Nonstop Mutation 1, Frame Shift Ins 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.3735G>T p.Q1245H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV100588461; called by muse, mutect2, varscan2
- ABCC1 | c.4186G>C p.D1396H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100578593; called by muse, mutect2, varscan2
- AC025165.3 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs747664076, COSV55744184; called by muse, varscan2
- ACSL4 | c.675C>G p.I225M (on ENST00000340800 / NM_022977.2; = p.I184M on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100538283, COSV100538680; called by muse, mutect2, varscan2
- AFG3L2 | c.1242G>C p.R414S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV52313854, COSV99301511; called by muse, mutect2, varscan2
- AHR | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748545788, COSV99619282; called by muse, mutect2, varscan2
- AKAP9 | c.3094G>T p.E1032* | Nonsense Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV100661923; called by muse, mutect2, varscan2
- AKAP9 | c.7890G>C p.L2630F (on ENST00000359028; = p.L2606F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.831); catalogued as COSV100661927, COSV62360249; called by muse, mutect2
- AKT1S1 | c.608C>T p.S203L (on ENST00000344175 / NM_001098633.4; = p.S223L on NM_032375.5) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100464863; called by muse, mutect2, varscan2
- ALG5 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99523513; called by muse, mutect2, varscan2
- AMOT | c.2213A>C p.N738T (on ENST00000371959 / NM_001113490.1; = p.N329T on NM_133265.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as COSV100494743; called by muse, mutect2, varscan2
- ANG | c.265C>G p.H89D | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100390827, COSV59012489; called by muse, mutect2
- APBB1IP | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV100770878; called by muse, mutect2, varscan2
- APBB3 | c.1118C>A p.T373N (on ENST00000357560 / NM_133173.2; = p.T380N on NM_006051.3) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100021105; called by muse, mutect2
- ARHGAP36 | c.54C>G p.I18M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV52263964, COSV99357274; called by muse, mutect2, varscan2
- ARHGAP44 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV99310099; called by muse, mutect2, varscan2
- ATG2A | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs371402696, COSV101033879; called by muse, varscan2
- BCR | c.2030C>G p.A677G | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100005985; called by muse, mutect2, varscan2
- BMPER | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV99778891; called by muse, mutect2, varscan2
- BRICD5 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236972751, COSV100063165, COSV100063511, COSV57027788; called by muse, mutect2, varscan2
- BUD13 | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV99496238; called by muse, mutect2, varscan2
- CCDC138 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.037); catalogued as COSV51699964, COSV99311279; called by muse, mutect2, varscan2
- CCR6 | c.969C>G p.F323L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV59475970; called by muse, mutect2, varscan2
- CD5 | c.125C>G p.S42W | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100759747, COSV104418369; called by muse, mutect2, varscan2
- CDK12 | c.3121G>C p.E1041Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71001352, COSV71001754, COSV71002334; called by muse, mutect2, varscan2
- CENPE | c.4768A>G p.K1590E | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.138); catalogued as rs1232095023, COSV99477020; called by muse, mutect2, varscan2
- CHD6 | c.5036G>A p.C1679Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100950566; called by muse, mutect2, varscan2
- CHL1 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99850158; called by muse, mutect2, varscan2
- CKM | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53465982; called by muse, mutect2, varscan2
- CLEC14A | c.628A>T p.T210S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as COSV100643497; called by muse, varscan2
- CNGB1 | c.2103C>G p.I701M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99201487; called by mutect2, varscan2
- CNTNAP1 | c.1097G>C p.G366A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99226128, COSV99226969; called by muse, mutect2, varscan2
- COLEC11 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99362856; called by muse, mutect2, varscan2
- COMP | c.1925C>A p.S642Y | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99721309; called by muse, varscan2
- CRYBB3 | c.190G>C p.G64R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308983; called by muse, mutect2, varscan2
- DHRS12 | c.511-1G>C p.X171_splice (on ENST00000444610 / NM_001377930.1; = p.X122_splice on NM_024705.2 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99523712; called by muse, mutect2
- DHX35 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV99326438; called by muse, mutect2, varscan2
- DLG5 | c.3428G>T p.G1143V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100967261; called by muse, mutect2, varscan2
- DNAH2 | c.9044A>C p.D3015A | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.304); catalogued as COSV101209019; called by muse, mutect2, varscan2
- DOCK11 | c.5270del p.K1757Rfs*4 | Frame Shift Del (DEL) | VAF 44/137 reads (32%) | catalogued as COSV52249172; called by pindel, varscan2
- DPYD | c.1822C>G p.L608V | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.688); catalogued as COSV100928649, COSV64613428; called by muse, mutect2, varscan2
- DUSP21 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.16); catalogued as COSV100173504; called by muse, varscan2
- DYRK2 | c.610G>C p.D204H (on ENST00000344096 / NM_006482.3; = p.D131H on NM_003583.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165189; called by muse, mutect2, varscan2
- EIF4G2 | c.1987C>A p.Q663K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV100379369; called by muse, mutect2, varscan2
- ENPP3 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371115901; called by muse, mutect2, varscan2
- EPM2AIP1 | c.19A>T p.R7* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99212332; called by muse, mutect2, varscan2
- EPYC | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as rs770231424, COSV53802276; called by muse, mutect2, varscan2
- ESRRG | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.406); catalogued as COSV63167942; called by muse, mutect2, varscan2
- EXOC3L4 | c.228C>G p.F76L | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101197559, COSV101197630; called by muse, mutect2, varscan2
- FAM135B | c.3998T>A p.L1333H | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99419145; called by muse, mutect2, varscan2
- FBXO9 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV99762248; called by muse, mutect2, varscan2
- FSIP1 | c.1611_1613del p.F537del | In Frame Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs1425864561; called by pindel, varscan2
- GCA | c.522C>G p.F174L | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.251); catalogued as COSV52025189, COSV99280663; called by muse, mutect2, varscan2
- GLYCTK | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772211266, COSV59794709; called by muse, varscan2
- GOLGA4 | c.5548C>A p.Q1850K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV100728655; called by muse, mutect2, varscan2
- GPAM | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV100788115; called by muse, mutect2, varscan2
- GPR89A | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100572357; called by muse, mutect2, varscan2
- GRIPAP1 | c.1559G>C p.G520A | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100904189; called by muse, mutect2, varscan2
- HCFC1 | c.5103G>C p.Q1701H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV100128445, COSV100130145, COSV60072675; called by muse, mutect2, varscan2
- HERC2 | c.10366G>A p.D3456N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.111); catalogued as COSV99871107; called by muse, mutect2, varscan2
- HIPK1 | c.3205A>T p.R1069W (on ENST00000369558 / NM_001369806.1; = p.R675W on NM_181358.2) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100478457; called by muse, mutect2, varscan2
- HOXB4 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100203680; called by muse, mutect2, varscan2
- HOXD13 | c.1010A>G p.K337R | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as rs753726144, COSV101184136; called by muse, mutect2, varscan2
- HR | c.1518G>C p.E506D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.978); catalogued as COSV100455646; called by muse, mutect2, varscan2
- IGLL5 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV101138628; called by muse, mutect2, varscan2
- IL23R | c.697G>C p.A233P | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV100724593; called by muse, mutect2, varscan2
- ING1 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.125); catalogued as COSV100311936; called by muse, mutect2, varscan2
- INHBE | c.299-2A>G p.X100_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99875191; called by muse, varscan2
- KHDRBS3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.71); catalogued as COSV100878428; called by muse, mutect2, varscan2
- KIF13A | c.2267G>C p.R756T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99433933; called by muse, mutect2
- KIF5B | c.2870G>C p.G957A | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100191419; called by muse, mutect2, varscan2
- KMT2C | c.13132G>A p.E4378K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV51498798; called by muse, mutect2, varscan2
- KMT2C | c.3295C>A p.L1099I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.656); catalogued as COSV100067177; called by muse, mutect2, varscan2
- KMT2C | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV100067181; called by muse, mutect2, varscan2
- KRT71 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57292142; called by muse, mutect2, varscan2
- LENG1 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1196663185, COSV99651509; called by muse, mutect2, varscan2
- LGALS12 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99736846; called by muse, mutect2, varscan2
- LRP4 | c.4573G>C p.D1525H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV101066885, COSV66135258; called by muse, mutect2, varscan2
- LRP5 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs1200833757, COSV99591445; called by mutect2, varscan2
- LRRC37A3 | c.2923C>A p.P975T | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV100140842; called by muse, mutect2
- LRRCC1 | c.102G>A p.Q34= | Splice Region (SNP) | VAF 19/39 reads (49%) | catalogued as COSV100835291, COSV64485328; called by muse, mutect2, varscan2
- LSAMP | c.572A>T p.Q191L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100369221; called by muse, mutect2
- MAN1C1 | c.422T>C p.F141S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs746317826, COSV99847816; called by muse, mutect2, varscan2
- MAN2B1 | c.1970C>G p.S657* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99666665; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV100186532; called by muse, mutect2, varscan2
- MCM5 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV99331488; called by muse, mutect2, varscan2
- MCTP1 | c.1142T>G p.L381R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100386350; called by muse, mutect2, varscan2
- MED29 | c.63G>C p.K21N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs765711223, COSV55394149, COSV99655552; called by muse, mutect2, varscan2
- MED9 | c.419T>A p.M140K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as COSV99245725; called by muse, mutect2, varscan2
- MGAT5B | c.2089G>C p.G697R (on ENST00000569840 / NM_001199172.2; = p.G695R on NM_144677.3) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100047034, COSV100047288; called by muse, mutect2
- MORC1 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV51717687, COSV99225133; called by muse, mutect2, varscan2
- MUC16 | c.16930C>T p.P5644S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); catalogued as rs767912953, COSV67494368; called by muse, mutect2, varscan2
- MUC16 | c.11278C>G p.P3760A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.249); catalogued as COSV101198195, COSV67458563; called by muse, mutect2
- MX1 | c.1609G>T p.V537L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0.046); catalogued as COSV99912452; called by muse, varscan2
- MYH6 | c.4648G>A p.E1550K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100676308; called by muse, varscan2
- NAA38 | c.175G>C p.D59H (on ENST00000575771 / NM_001320925.2; = p.D107H on NM_032356.5) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99640759; called by mutect2, varscan2
- NAP1L3 | c.29C>G p.S10W | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.488); catalogued as COSV100220165, COSV59074135; called by muse, mutect2, varscan2
- NID1 | c.3178G>C p.E1060Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV99937019; called by muse, mutect2, varscan2
- NLRP6 | c.2595G>T p.K865N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.108); catalogued as COSV100380935, COSV100381072; called by muse, mutect2
- NOL11 | c.785G>C p.G262A | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.48); catalogued as rs755793736, COSV99474840; called by muse, mutect2, varscan2
- NR2C1 | c.1210T>A p.S404T | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100280208; called by muse, mutect2, varscan2
- NSDHL | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100938598; called by muse, mutect2, varscan2
- NUP210L | c.1226A>G p.E409G | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99667265; called by muse, mutect2, varscan2
- NXF1 | c.1756C>G p.Q586E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV99585757; called by muse, mutect2, varscan2
- OR10A3 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100660214; called by muse, mutect2, varscan2
- OR2T3 | c.582C>G p.C194W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100613082; called by muse, mutect2, varscan2
- OR8D1 | c.739G>C p.A247P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100766535; called by muse, mutect2, varscan2
- PCDHGA5 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.358); catalogued as rs749640886, COSV53974505; called by muse, mutect2, varscan2
- PELI2 | c.1187C>G p.A396G | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99952881; called by muse, mutect2
- PIKFYVE | c.5836A>T p.M1946L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as COSV100009829; called by muse, mutect2, varscan2
- POLE | c.2498G>A p.G833D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100265409; called by muse, mutect2, varscan2
- POLR2B | c.3361C>G p.L1121V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV99825256; called by muse, mutect2, varscan2
- PPIL4 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as rs761631618, COSV99481423; called by muse, mutect2, varscan2
- PPP2R5B | c.59C>G p.S20W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99375854; called by muse, mutect2, varscan2
- PROX1 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs761648947, COSV54776479, COSV99798715; called by muse, mutect2, varscan2
- PSME4 | c.401C>A p.S134* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV101122247; called by muse, mutect2, varscan2
- PTDSS2 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs140991730; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.691G>A p.E231K (on ENST00000421990 / NM_001136042.2; = p.E213K on NM_025267.3) | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.068); catalogued as rs113394106, COSV100799198; called by muse, mutect2, varscan2
- PTPN18 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99447422; called by muse, mutect2, varscan2
- PYGB | c.1193C>G p.P398R | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53821776, COSV53823401; called by mutect2, varscan2
- RASA2 | c.2095G>A p.V699I | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776746640, COSV53936376; called by muse, mutect2, varscan2
- RASD2 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99332663; called by muse, mutect2, varscan2
- RASSF5 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs781811232, COSV100795044, COSV100795339; called by muse, mutect2, varscan2
- RBM14 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV100036535; called by muse, mutect2, varscan2
- RBM5 | c.2119G>C p.E707Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100762152; called by muse, mutect2, varscan2
- RDH12 | c.166G>C p.A56P | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99961768; called by muse, mutect2, varscan2
- RHBG | c.646T>G p.Y216D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99659166; called by muse, mutect2, varscan2
- RICTOR | c.2250G>A p.W750* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV57128296; called by muse, mutect2, varscan2
- SAV1 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100220638; called by muse, mutect2
- SCARA3 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100106395; called by muse, mutect2, varscan2
- SCMH1 | c.1157G>A p.G386E (on ENST00000326197 / NM_001031694.2; = p.G339E on NM_012236.4) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100401369; called by muse, mutect2, varscan2
- SDE2 | c.1225A>C p.M409L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV99682457; called by muse, mutect2, varscan2
- SERPINA11 | c.-2G>C | Splice Region (SNP) | VAF 6/9 reads (67%) | catalogued as COSV100593942; called by muse, varscan2
- SERTAD2 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV100512108; called by muse, mutect2, varscan2
- SHOC1 | c.1437del p.E481Kfs*22 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as COSV104404837; called by mutect2, pindel, varscan2
- SIGLEC1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.314); catalogued as COSV99163316; called by muse, mutect2, varscan2
- SIGLEC5 | c.1534T>A p.L512M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.473); catalogued as COSV99707125; called by muse, mutect2, varscan2
- SLC17A6 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV99580793; called by muse, mutect2, varscan2
- SLC44A4 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs200350113, COSV99998617; called by muse, mutect2, varscan2
- SLC9C1 | c.2210del p.R737Kfs*2 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as COSV99997036, COSV99997100; called by mutect2, pindel
- SLX4 | c.4850C>G p.S1617* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99567623; called by muse, mutect2, varscan2
- SMARCA4 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV100758176; called by muse, mutect2, varscan2
- SMC6 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as rs367969244; called by muse, mutect2, varscan2
- SMG1 | c.3232G>A p.E1078K | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV101245206; called by muse, varscan2
- SMYD4 | c.2107G>A p.D703N | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770190374, COSV100562925; called by muse, mutect2, varscan2
- SOS1 | c.3150G>A p.M1050I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as rs1194032302, COSV101216575; called by muse, mutect2, varscan2
- SPARCL1 | c.1771C>G p.P591A | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99215288; called by muse, mutect2, varscan2
- SPDYE3 | c.1224C>G p.F408L | Missense Mutation (SNP) | VAF 152/311 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV100193371; called by muse, mutect2
- SPINDOC | c.620C>G p.T207R | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.045); catalogued as COSV99588445; called by muse, mutect2, varscan2
- STAG2 | c.629C>A p.S210* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as COSV99492352; called by muse, mutect2, varscan2
- STRN3 | c.1890G>A p.K630= (on ENST00000357479 / NM_001083893.2; = p.K546= on NM_014574.4) | Splice Region (SNP) | VAF 10/51 reads (20%) | catalogued as rs1438368204, COSV100670352; called by muse, mutect2, varscan2
- STXBP5L | c.3149G>A p.R1050Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761215215, COSV56517780; called by muse, mutect2, varscan2
- SYNPO2 | c.2784C>G p.I928M | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100204908; called by muse, mutect2, varscan2
- TAC3 | c.234G>T p.E78D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV55647851; called by muse, mutect2, varscan2
- TARBP2 | c.565C>T p.R189C (on ENST00000266987 / NM_134323.2; = p.R168C on NM_004178.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1340168203, COSV57198937; called by muse, mutect2, varscan2
- TAT | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV63533461; called by muse, mutect2, varscan2
- TBC1D10A | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV99304481; called by muse, mutect2, varscan2
- TCF20 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.44); catalogued as COSV100166268; called by muse, mutect2, varscan2
- TENM4 | c.3493G>A p.A1165T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as rs550968777, COSV53651170; called by muse, mutect2, varscan2
- THEMIS | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV64072264; called by muse, mutect2
- THRAP3 | c.2438G>A p.R813K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); catalogued as rs1160939155, COSV100663199; called by muse, mutect2, varscan2
- THSD1 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1202013298, COSV99318705; called by muse, mutect2, varscan2
- TLE2 | c.1718T>C p.V573A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99504037; called by muse, mutect2, varscan2
- TMA16 | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV100667307; called by muse, mutect2
- TMEM51 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV101051480; called by muse, mutect2, varscan2
- TMEM63C | c.393C>G p.I131M | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.043); catalogued as COSV100029217; called by muse, mutect2, varscan2
- TNK2 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1275695671, COSV100361022; called by muse, mutect2, varscan2
- TOX4 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.853); catalogued as COSV99398034; called by muse, mutect2, varscan2
- TP53TG5 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV101022299, COSV65577350; called by muse, mutect2, varscan2
- TRA2B | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.042); catalogued as COSV99373172; called by muse, mutect2
- TSFM | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs770248416, COSV100103482; called by muse, mutect2
- TTC24 | c.854C>G p.A285G | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as COSV100964306, COSV63998350; called by muse, mutect2, varscan2
- TTN | c.17145G>C p.K5715N (on ENST00000591111; = p.K4788N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | PolyPhen benign (0.038); catalogued as COSV100594948, COSV60141847; called by muse, mutect2, varscan2
- TULP4 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV100893141; called by muse, mutect2, varscan2
- TWF1 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1428746026, COSV100285949; called by muse, mutect2, varscan2
- UBE2M | c.486G>C p.Q162H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99447946; called by muse, mutect2, varscan2
- UNC13C | c.4397C>T p.S1466L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99511938; called by muse, mutect2, varscan2
- VPS16 | c.1758C>A p.N586K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV100988281; called by muse, mutect2, varscan2
- XIRP1 | c.3234G>T p.Q1078H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV100453394; called by muse, mutect2, varscan2
- ZFP36L2 | c.635G>A p.C212Y | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs973243276, COSV99143553; called by muse, mutect2, varscan2
- ZFPM1 | c.996G>C p.K332N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100128189; called by muse, mutect2, varscan2
- ZNF235 | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV99349262; called by muse, mutect2, varscan2
- ZNF285 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100449845; called by muse, mutect2, varscan2
- ZNF479 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100482489, COSV58635651, COSV58636836; called by muse, mutect2
- ZNF529 | c.761A>C p.Y254S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV100485086; called by muse, mutect2, varscan2
- ZNF57 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as rs763016352, COSV100182742; called by muse, mutect2
- ZNF675 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100704899; called by muse, mutect2, varscan2
- ZNF675 | c.1006G>T p.G336* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100704902; called by muse, mutect2, varscan2
- ZNF804A | c.2344G>A p.D782N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV100166488; called by muse, mutect2, varscan2
- ZPLD1 | c.795G>C p.E265D (on ENST00000466937 / NM_001329788.1; = p.E281D on NM_175056.2) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV100082926; called by muse, mutect2, varscan2
- ACP4 | c.451-8_461del p.X151_splice | Splice Site (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.1702T>A p.W568R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADD2 | c.760_778del p.G254Tfs*28 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel, varscan2
- AJUBA | c.266_296del p.F89Cfs*143 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by pindel, varscan2
- ATM | c.8320G>T p.V2774F | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.096); called by muse, mutect2
- BBS2 | c.428_457del p.A143_S152del | In Frame Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- CDC27 | c.2312_2331del p.A771Gfs*3 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- CER1 | c.222_231del p.Q75Rfs*39 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- DEFB129 | c.225_241del p.E77Afs*8 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- EP300 | c.3262-10_3269del p.X1088_splice | Splice Site (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel
- FBN2 | c.5925dup p.E1976* | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- GEN1 | c.2140_2182del p.D714Cfs*11 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, pindel
- LUZP1 | c.2264_2270del p.I755Nfs*9 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- PLS1 | c.235-17_237del p.X79_splice | Splice Site (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- PSG3 | c.443_457del p.K148_S152del | In Frame Del (DEL) | VAF 42/126 reads (33%) | called by mutect2, varscan2
- PYGM | c.1967_1969+20del p.X656_splice | Splice Site (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- RASGRF1 | c.1607-9_1617del p.X536_splice | Splice Site (DEL) | VAF 13/48 reads (27%) | called by mutect2, pindel, varscan2
- SPEN | c.7992_8012del p.N2666_V2672del | In Frame Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- TAF7L | c.624_628del p.E209Gfs*17 | Frame Shift Del (DEL) | VAF 7/85 reads (8%) | called by mutect2, pindel
- TBC1D10A | c.700_705+5del p.X234_splice | Splice Site (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- TLNRD1 | c.1081G>T p.V361L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- TRA2B | c.857_*2del | Nonstop Mutation (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- TRAV16 | c.261_263del p.S88del | In Frame Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- ZNF488 | c.1015C>G p.H339D | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFG1L | c.918C>T p.V306= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV100933853; called by muse, mutect2, varscan2
- AKAP9 | c.3210G>A p.L1070= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100661924, COSV62346753; called by muse, varscan2
- ALDH1L1 | c.2667G>A p.L889= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV99856516; called by muse, mutect2, varscan2
- ANAPC11 | c.63G>A p.E21= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV100485758; called by muse, mutect2, varscan2
- ASPM | c.2007C>T p.F669= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV99659576; called by muse, mutect2, varscan2
- BMP8B | c.795G>C p.V265= | Silent (SNP) | VAF 8/160 reads (5%) | catalogued as COSV100560181; called by muse, mutect2
- CACNA1E | c.849C>T p.I283= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs759787187, COSV100701292; called by muse, mutect2, varscan2
- CCDC191 | c.2241C>G p.V747= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99877930; called by muse, mutect2, varscan2
- CHD5 | c.3648C>G p.V1216= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99312543; called by muse, mutect2, varscan2
- COL9A1 | c.870C>G p.G290= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV100294096, COSV57880935; called by muse, mutect2, varscan2
- CREB3L4 | c.630C>A p.L210= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99665602; called by muse, mutect2, varscan2
- CSF3R | c.309G>A p.L103= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV58973381; called by muse, mutect2, varscan2
- CSMD1 | c.9861G>C p.V3287= (on ENST00000520002; = p.V3286= on NM_033225.6) | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs769054501, COSV59306603; called by muse, mutect2, varscan2
- CSMD1 | c.1941T>C p.S647= (on ENST00000520002; = p.S646= on NM_033225.6) | Silent (SNP) | VAF 18/31 reads (58%) | catalogued as COSV100144102; called by muse, mutect2, varscan2
- CYBB | c.1515G>A p.L505= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as CD106283, COSV66086183; called by muse, mutect2, varscan2
- DAPK2 | c.144G>A p.E48= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV99977077; called by muse, mutect2, varscan2
- DCAF13 | c.183G>A p.S61= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs746318456, COSV99885023; called by muse, varscan2
- DENND2D | c.1086C>T p.I362= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100718537; called by muse, mutect2, varscan2
- DNTTIP2 | c.1335C>G p.L445= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs759266462, COSV100785139; called by muse, mutect2, varscan2
- DUOX2 | c.4029C>T p.L1343= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101199568; called by muse, mutect2, varscan2
- EVPL | c.321C>T p.L107= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV100043983; called by muse, mutect2, varscan2
- FFAR1 | c.165G>A p.L55= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs769406381, COSV99322870; called by muse, varscan2
- FOS | c.201C>T p.I67= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs747221475, COSV100338417; called by muse, mutect2, varscan2
- GRN | c.45G>T p.V15= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99274589; called by muse, mutect2, varscan2
- H2AC15 | c.249C>T p.H83= | Silent (SNP) | VAF 25/174 reads (14%) | catalogued as COSV100356907; called by muse, mutect2, varscan2
- HDAC6 | c.2862G>A p.E954= | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as COSV100490578; called by muse, mutect2, varscan2
- HESX1 | c.378C>G p.V126= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV55843757, COSV99907674; called by muse, mutect2, varscan2
- INPP4A | c.1962C>T p.F654= (on ENST00000074304 / NM_001134224.1; = p.F615= on NM_001566.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99302601; called by muse, mutect2, varscan2
- INPP5D | c.2733C>T p.I911= (on ENST00000445964 / NM_001017915.3; = p.I910= on NM_005541.5) | Silent (SNP) | VAF 33/53 reads (62%) | catalogued as COSV100856520; called by muse, mutect2, varscan2
- IRS2 | c.1758G>A p.P586= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV101018830; called by muse, mutect2, varscan2
- ITPR3 | c.399G>C p.L133= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100966944; called by muse, mutect2, varscan2
- MAMDC2 | c.124C>T p.L42= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1236482744, COSV101015236, COSV65861603; called by muse, mutect2, varscan2
- MAP3K9 | c.3243G>A p.V1081= (on ENST00000554752 / NM_001284230.1; = p.V1095= on NM_033141.4) | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV101173475; called by muse, mutect2, varscan2
- MKLN1 | c.1425C>G p.G475= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100759682; called by muse, mutect2, varscan2
- MRPS25 | c.273G>A p.E91= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99507651; called by muse, mutect2, varscan2
- NBEA | c.3909T>A p.V1303= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100076957; called by muse, mutect2, varscan2
- NRXN1 | c.2076G>A p.R692= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs267599408, COSV100453385; called by muse, mutect2, varscan2
- PCK2 | c.624C>G p.V208= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99394100; called by muse, mutect2
- PIGV | c.1275G>A p.E425= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV50299243; called by muse, mutect2, varscan2
- PLA2G4D | c.2433G>A p.A811= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs968717385, COSV51818843; called by muse, mutect2, varscan2
- PLAU | c.483A>C p.P161= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV101032245; called by muse, mutect2
- PLEKHG4B | c.1431G>A p.Q477= (on ENST00000283426; = p.Q833= on NM_052909.5) | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99359822; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.471G>A p.L157= (on ENST00000421990 / NM_001136042.2; = p.L139= on NM_025267.3) | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs1217235462, COSV100799199; called by muse, mutect2, varscan2
- PTPRT | c.2124C>T p.L708= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100625377; called by muse, mutect2, varscan2
- PUM1 | c.2817G>A p.Q939= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV57088252; called by mutect2, varscan2
- PWWP3B | c.309G>A p.L103= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as COSV100530934; called by muse, mutect2, varscan2
- RIMS3 | c.588G>A p.K196= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV101013270; called by muse, mutect2, varscan2
- ROS1 | c.3714C>G p.L1238= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100876511, COSV100876666, COSV63862848; called by muse, mutect2, varscan2
- SLC10A5 | c.834C>G p.L278= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs775542585, COSV101594245; called by muse, mutect2, varscan2
- SLC41A2 | c.1428G>A p.V476= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99316156; called by muse, varscan2
- SLC46A1 | c.1137C>G p.L379= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99134927; called by muse, mutect2, varscan2
- STAB1 | c.3657C>G p.V1219= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs377308263; called by muse, mutect2, varscan2
- SULF2 | c.1416G>A p.L472= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100736998; called by muse, varscan2
- TAOK2 | c.3096G>A p.L1032= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99662854; called by muse, mutect2, varscan2
- TMEM116 | c.657A>C p.S219= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100702120; called by muse, mutect2, varscan2
- TMEM236 | c.867C>G p.L289= | Silent (SNP) | VAF 26/191 reads (14%) | called by muse, mutect2, varscan2
- UNC79 | c.993G>A p.A331= (on ENST00000393151 / NM_001346218.2; = p.A154= on NM_020818.5) | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs757821034, COSV56387184; called by muse, mutect2, varscan2
- UQCRQ | c.204G>A p.E68= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV99737108; called by muse, mutect2, varscan2
- WIPI2 | c.777C>T p.D259= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as rs747607185, COSV99993149; called by muse, varscan2
- ZNF318 | c.1647A>G p.E549= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100545953; called by muse, mutect2
- ZNF335 | c.3936C>G p.G1312= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100532653; called by muse, mutect2
- ZSCAN18 | c.1446C>T p.R482= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs1326876692, COSV53732424; called by muse, mutect2, varscan2
- AL031659.1 | chr20:37168134 A>C | 5'Flank (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2
- BCR | c.1279+16993_1279+17019del | Intron (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel
- NBR2 | n.328C>T | RNA (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- POLH | c.*5725G>A | 3'UTR (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- SHMT1 | c.243-42C>A | Intron (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- STRN3 | c.282+11252C>A | Intron (SNP) | VAF 5/97 reads (5%) | catalogued as rs1214688306, COSV62578594; called by muse, mutect2
- TTN | c.10361-4100G>A | Intron (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100594950, COSV59959751; called by muse, mutect2, varscan2
- ZSCAN32 | c.915-41G>C | Intron (SNP) | VAF 19/47 reads (40%) | catalogued as COSV100514184; called by muse, mutect2, varscan2
- ZSCAN32 | c.914+169G>A | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100514185; called by muse, mutect2, varscan2
- ZSCAN32 | c.839-678G>T | Intron (SNP) | VAF 12/56 reads (21%) | catalogued as COSV100514188; called by muse, mutect2, varscan2
